Gene-level copy-number profile of tumor specimen C3N-00390-01 from CPTAC case C3N-00390, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 58.2 years (21,263 days).
Specimen C3N-00390-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a6ea3859-8e3e-43ec-99f9-91b8b630d926.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00390-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/69c5d369-ec3e-40a7-9966-2daeb1499f33

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 13; copy number 2: 7,563; copy number 3: 84; copy number 4: 35,614; copy number 5: 316; copy number 6: 15,290; copy number 7: 13.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:15,541,436–15,722,608, 15 genes: AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1.
- chr22:15,784,959–15,829,984, 5 genes: DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
